Gene-level copy-number profile of tumor specimen TCGA-CR-6474-01A from TCGA case TCGA-CR-6474, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.6 years (18,840 days).
Specimen TCGA-CR-6474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ca45c42f-9a46-4fcf-901a-b8a6e5c3f086.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6474-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5357b37-856c-4792-98f4-66271578a974

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 20,876; copy number 2: 31,177; copy number 3: 1,839; copy number 4: 3,469; copy number 5: 1,148; copy number 6: 1,071; copy number 7: 22; copy number 8: 81; copy number 9: 65; copy number 21: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6474-01A-11D-1869-01): tumor purity 0.2, ploidy 4.01, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr3:41,162,287–41,260,096, 3 genes: AC009743.1, MRPS31P1, CTNNB1.
- chr11:79,191,558–79,193,160, 1 gene: AP001547.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,447 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–23,329,892, 380 genes, copy number 5 (broad region; genes not listed).
- chr5:23,456,468–23,456,850, 1 gene, copy number 5: AC109445.1.
- chr7:70,972–62,275,678, 1,079 genes, copy number 6–8 (broad region; genes not listed).
- chr8:36,308,245–38,601,200, 65 genes, copy number 9 (broad region; genes not listed).
- chr8:96,645,242–145,066,685, 767 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:68,891,276–72,005,715, 98 genes, copy number 6–21 (broad region; genes not listed).
- chr11:72,014,291–72,020,910, 1 gene, copy number 21: AP002490.1.
- chr18:30,984,106–33,441,101, 56 genes, copy number 6: RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1.

Autosomal genes at a single copy (total copy number 1): 20,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
